Gene-level copy-number profile of tumor specimen AP-LWHD-FC from APOLLO case AP-LWHD, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2.
Specimen AP-LWHD-FC: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cc90266c-e33a-4ad5-9151-4179103e0189.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-LWHD-GB (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/d4c0e399-9d51-4c7a-902a-5e4d2722f67e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 7,731; copy number 2: 45,892; copy number 3: 3,936; copy number 4: 433; copy number 5: 478; copy number 6: 102; copy number 7: 151; copy number 8: 102; copy number 9: 29.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:241,916,123–241,999,098, 4 genes: RPL23AP20, BECN2, CFL1P4, MAP1LC3C.
- chr2:89,319,625–89,600,680, 3 genes: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr3:90,202,316–90,261,708, 2 genes: PROS2P, HSPE1P19.
- chr6:73,209,746–73,653,992, 24 genes (within-gene range 0–1): AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15.
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr10:38,403,189–38,452,153, 1 gene (within-gene range 0–2): AL133216.2.
- chr10:38,452,987–38,783,108, 10 genes: CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr12:38,078,529–38,087,392, 2 genes: AK6P2, CLUHP8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 862 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,288,596–147,788,953, 40 genes, copy number 8: RNU6-1071P, NUDT4P2, SEC22B4P, PPIAL4H, RNVU1-29, RNVU1-25, AC245407.1, HYDIN2, RNA5SP536, AC241929.1, NBPF12, PFN1P8, AC244394.3, AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2.
- chr1:149,676,851–155,331,114, 331 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr1:158,445,068–161,069,970, 117 genes, copy number 5–6 (broad region; genes not listed).
- chr1:161,983,192–162,787,405, 20 genes, copy number 6: OLFML2B, AL590408.1, NOS1AP, AL450163.1, MIR4654, AL512785.1, RNA5SP61, MIR556, AL512785.2, SPATA46, C1orf226, SH2D1B, SLAMF6P1, UHMK1, UQCRBP2, AL596325.1, UAP1, AL596325.2, DDR2, RN7SL861P.
- chr1:184,690,237–187,714,735, 47 genes, copy number 5: EDEM3, NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, PTGS2, PACERR, PLA2G4A, LINC01036, AL391813.1, FDPSP1, AL357559.1, SLC4A1APP2, AL645474.1.
- chr1:188,508,538–191,228,467, 25 genes, copy number 5–8: AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75, RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680.
- chr1:191,858,707–191,890,229, 1 gene, copy number 5 (within-gene range 4–5): AL359081.1.
- chr1:192,716,132–193,060,080, 9 genes, copy number 5 (within-gene range 4–5): RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B.
- chr1:202,331,657–204,494,724, 76 genes, copy number 5 (broad region; genes not listed).
- chr1:209,147,220–209,857,565, 21 genes, copy number 5: AC092810.2, AC092810.1, TFDP1P1, ATP5MC2P1, LINC01696, LINC01698, MIR205HG, MIR205, AL023754.1, AL023754.2, CAMK1G, LAMB3, MIR4260, HSD11B1-AS1, G0S2, HSD11B1, ADORA2BP1, TRAF3IP3, C1orf74, IRF6, UTP25.
- chr1:212,363,928–213,015,867, 22 genes, copy number 5: PACC1, NENF, LINC02771, LINC01740, AC092803.1, AC092803.4, ATF3, AL590648.2, FAM71A, AL590648.1, LINC02773, BATF3, NSL1, TATDN3, AC104333.3, SPATA45, FLVCR1-DT, AC104333.1, AC104333.2, FLVCR1, VASH2, ANGEL2.
- chr1:229,425,020–230,612,412, 21 genes, copy number 5: AL160004.2, ACTA1, NUP133, AL160004.1, AL121990.1, ABCB10, RNU4-21P, RNA5SP78, HMGN2P19, TAF5L, URB2, AL354983.1, HMGB1P26, LINC01682, LINC01736, GALNT2, AL136988.2, AL136988.1, PGBD5, LINC01737, AL158214.1.
- chr20:31,819,308–32,439,319, 23 genes, copy number 5: MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, KIF3B, AL121583.1, ASXL1.
- chr20:52,972,358–53,495,330, 1 gene, copy number 5 (within-gene range 3–5): TSHZ2.
- chr20:53,137,293–53,141,169, 1 gene, copy number 5: AL391097.3.
- chr20:53,255,979–59,113,631, 107 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,726. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
